Gene-level copy-number profile of tumor specimen ALCH-AELG-TTP1-A from ALCHEMIST case ALCH-AELG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.8 years (25,847 days).
Specimen ALCH-AELG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69d44490-411f-4a3b-b4cf-081113d74bf7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AELG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/56812433-c502-419d-b102-f3c18bc5b038

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 11,471; copy number 2: 44,118; copy number 3: 2,723; copy number 4: 3; copy number 9: 1; copy number 11: 3; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,234,774–9,271,337, 1 gene: H6PD.
- chr4:1,574,062–1,580,253, 1 gene: AC147067.1.
- chr12:131,447,337–131,455,436, 1 gene: AC073578.2.
- chr14:105,836,765–105,845,678, 1 gene (within-gene range 0–1): IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,945,389, 42 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1.
- chr15:25,159,221–25,175,008, 5 genes (within-gene range 0–2): SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3.
- chr15:25,250,859–25,250,940, 1 gene (within-gene range 0–2): SNORD115-44.
- chr15:74,598,919–74,599,397, 1 gene (within-gene range 0–2): AC100835.2.
- chr16:33,802,764–33,827,661, 3 genes: IGHV3OR16-12, AC136428.3, IGHV3OR16-13.
- chr16:33,907,419–33,976,346, 6 genes (within-gene range 0–2): ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5.
- chr17:3,608,240–3,696,240, 9 genes (within-gene range 0–1): SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5.
- chr17:77,469,068–77,472,770, 2 genes (within-gene range 0–1): AC111170.2, AC111170.1.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.
- chr22:47,115,838–47,117,217, 1 gene (within-gene range 0–2): FP325331.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–139,612, 3 genes, copy number 9–15 (within-gene range 7–15): AC069287.1, CICP23, LINC01001.
- chr22:20,338,805–20,354,387, 3 genes, copy number 11 (within-gene range 2–11): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 11,471. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
